Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AFFX, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AFFX-TTP1-A (Primary Tumor).

[page 1 of 8]
Patient Name:

MR#:

Date of Birth:

Submitting Physician:

Account:

Age:

Sex:

Case Number:

Collection Date:

Received Date:

Location:

+6

+6

Supplemental Report

Analysis for Her-2/neu amplification was performed by FISH at [REDACTED]. The result is **Positive for Her-2/neu gene amplification** with a ratio of Her-2/neu to chromosome 17 signals of **9.8**.

Tissue Source

ESOPHAGUS, mass @ 32-40 cm-Biopsy

Clinical Information

Esophageal mass, Barrett's.

Gross Description

Received in formalin, labeled "biopsy esophageal mass 32-40 cm" are multiple irregular and friable white-tan to pink portions of mucosal tissue ranging from 0.2-0.5 cm in greatest dimension, which are submitted in toto. 1/multiple [REDACTED]

Diagnosis

ESOPHAGUS, mass @ 32-40 cm-Biopsy

ULCERATED POORLY DIFFERENTIATED ADENOCARCINOMA

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 2 of 8]
Image

SPECIMEN ID:
REQUESTION:
COLLECTED:
RECEIVED:
REPORTED:

Cytogenetics FISH Report

+6

+10

CYTOMETRIC (FISH) HER2 (neu. Prolifer. Block)

Case Number:
Specimen Source:
Clinical History:

Esophagus
Adenocarcinoma: HER2
HER2 Not Available

Interphase Cells:
Metaphase Cells:

37
0

Fish Results

POSITIVE for HER2 (ERBB2) AMPLIFICATION

RATIO of HER2 to D17Z1 is 0.6 (average count: HER2: 27.8; D17Z1: 2.6)

Interpretation / Comments

The HER2 FISH assay (Abbott Molecular) revealed amplification of HER2 (ERBB2).

A ratio of ≥ 2.0 is considered to indicate amplification based on the ToGA trial. Clinical correlation is recommended.

Current NCCN guidelines state that the ToGA study establishes Trastuzumab plus chemotherapy as a new standard of care for the treatment of patients with HER2-expressing advanced gastric and

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 3 of 8]
PATIENT INFORMATION:

REPORT STATUS: FINAL

ORDERING PHYSICIAN:

Cytogenetics FISH Report

COLLECTED: +6
RECEIVED: +10
REPORTED: +10

postmenopausal cancers. In the TCGA trial these patients with positive FISH results, whose cancers had high expression of HER2 protein (immunohistochemistry 3+ or 2+), showed additional benefit over those whose tumors had low expression of HER2 protein (HER2 0 or 1+). Therefore, correlation of the FISH and IHC results for HER2 is recommended.

Slides from this sample were evaluated by an in-house pathologist and deemed adequate for HER2 FISH analysis. The formalin fixation time was not provided. Controls were performed and provided the anticipated results. The mapping method was manual. This case has been reviewed by at least 2 observers.

This pre-treatment and hybridization steps of the FDA-approved method have been optimized and these changes have been validated. The performance characteristics of the assay have been determined by [redacted] Performance characteristics refer to the analytical performance of the test.

[redacted] Trastuzumab in combination with chemotherapy versus chemotherapy alone for treatment of HER2-positive advanced gastric or gastroesophageal junction cancer (TCGA): a phase 3, open-label, randomised controlled trial.

FISH (SCN: dup HNF1A 17x10²-4, HER2x20-35x30)

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

Page 2

Charges by Specimen

Specimen

1

Code

CPT

Count

1

[page 4 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Class: Emergency

CT Chest Abdomen Pelvis w IV Contrast

Reason for Exam: worsening left flank pain, eval masses, eval kidney

Date: [REDACTED]

CC:

Imaging Result

CT scan of the chest abdomen and pelvis patient had a recent noncontrast CT from [REDACTED] had demonstrated lymphadenopathy in the retroperitoneum. The patient is apparently having left flank pain.

Today's study is performed with IV contrast.

Images were acquired from the thoracic inlet to the upper abdomen. Thyroid gland is unremarkable

Images through the mediastinum demonstrate no significant adenopathy. No pericardial effusions no pleural effusions. There is a small hiatal hernia. There appears to be some mild circumferential thickening of the distal esophagus this may simply be due to a peristaltic wave. Clinical correlation recommended. No discrete mass is seen in the esophagus. The stomach is partially filled with oral contrast.

The lung parenchyma demonstrates atelectatic changes in lung bases. No parenchymal nodules or masses are seen no endoluminal lesions in the trachea or proximal bronchi.

The pulmonary arteries are well opacified there are no filling defects. Abdomen enhanced images through the liver demonstrate no focal lesions.

Again midline in the abdomen there is a partially calcified 3 cm x 3.1 cm mass in the upper abdomen seen best on image [REDACTED]. This mass appears to be coalescent with soft tissue attenuating lesions are continued down along the retroperitoneum posterior to the pancreas likely representing adenopathy. This area continues inferiorly measures approximately 2.5 cm in transverse dimension and is best seen in image [REDACTED] the spleen is not enlarged.

There is a soft tissue attenuating lesion posterior to the body of the pancreas on image [REDACTED] near the splenic artery measuring 13 mm.

Superiorly adjacent to the partially calcified soft tissue mass in the upper abdomen near the lesser curvature of the stomach there is another soft tissue mass measuring 2.8 cm this also is seen on the prior exam. The soft tissue rounded masses likely all represent retroperitoneal lymphadenopathy. There is a mantle of adenopathy seen above the left renal vein this area measures 2.9 cm this also was seen on the prior study. Lymphadenopathy continues below the level of the renal veins with lymph nodes noted between the aorta inferior cava measuring 19 mm and adjacent to the aorta measuring 16 mm seen image [REDACTED]

The appendix is seen on image [REDACTED] and is normal

[page 5 of 8]
The colon is decompressed there are some scattered diverticuli.

The bladder is minimally distended.

The patient is a small inguinal hernia left containing some mesenteric fat.

The kidneys are normal in appearance. No focal lesions the spleen is not enlarged. It measures 11.6 cm.

The pancreas is unremarkable in appearance.

The gallbladder is unremarkable in appearance.

The adrenal glands are unremarkable in appearance.

No collections are seen in the pelvis. The osseous structures are unremarkable.

IMPRESSION

Impression: Diffuse retroperitoneal adenopathy. The solid organs are unremarkable in appearance.

The distal esophagus demonstrates a hiatal hernia. There is some circumferential thickening to the distal esophagus but no discrete mass is seen. This thickening is nonspecific. Circumferential lesion at distal esophagus cannot be excluded. A esophagram or endoscopy may be useful.

The lymphadenopathy is largest just at the GE junction as it continues down into the retroperitoneum. In one of the lymph nodes does appear to be at least partially calcified.

The liver spleen pancreas gallbladder kidneys adrenals are all normal in appearance.

[page 6 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Class: Outpatient
PET CT Skull to Thigh Area
Subsequent
Reason for Exam: gastric
cancer, reassess post treatment
Date: [REDACTED] +185

CC:

Imaging Result

CLINICAL DATA: Gastric cancer, reassess posttreatment. History of lymphadenopathy, stage IV adenocarcinoma of the esophagus, metastasis supraclavicular lymph node.

This study was compared to the prior study of [REDACTED] +77

Approximately one hour after the intravenous administration of 13.88 mCi of F18 fluorodeoxyglucose, an attenuation corrected PET imaging study was performed with images obtained from the level of the skull base to the proximal femurs. Injection by left antecubital introduction. Patient's blood sugar 94 mg/dL.

On today's study no suspicious uptake in the chest, abdomen or pelvis is seen.

On the attenuation CT a calcified lymph node is again seen behind the liver in the porta hepatis region. This was present on the prior PET study without significant change in the density/mineralization. The AP diameter of the lymph node is 2.6 cm previously approximately 2.8 cm. A few nonspecific retroperitoneal lymph nodes are otherwise seen.

No significant change otherwise noted.

IMPRESSION: No suspicious uptake. Calcified lymph node seen in the right upper abdomen near the diaphragm was present on the prior study and is not significantly changed approximately 2.6 cm in size on today's study. No significant change otherwise seen.

Reported And Signed By: [REDACTED]

[page 7 of 8]
Name

MRN

DOB

Class: Outpatient

PET CT Skull to Thigh Area

Subsequent WITHOUT
diagnostic CTReason for Exam: Hx her 2 +
esophageal adenocarcinoma,
restaging on maintenance
herceptin

Date:

CC:

Imaging Result

CLINICAL DATA: History of esophageal adenocarcinoma. Restaging.

Approximately 1 hour after the intravenous administration of 12.51 mCi F-18 fluorodeoxyglucose, an attenuation corrected PET imaging study was performed with images obtained from the level of the skull base to the proximal femurs. The study is compared to prior study dated +279

Additional studies including the initial PET study dated +14 as well as CT of the abdomen and pelvis of +3 and +5 were also reviewed.

On today's study in the neck no suspicious uptake is seen.

In the chest there is now activity seen associated with enlarging left axillary nodes representing unfavorable change compared to the prior study. On image there is a lymph node now seen with a long axis measurement of approximately 19 mm and shows an SUV of 2.1 with other areas of activity also seen associated with lymph nodes in the left axilla and representing unfavorable change.

In addition there is now some uptake seen associated with the distal esophagus just above the GE junction with an SUV of 2.9. This also represents a change compared to the prior study and is suspicious for unfavorable change possible recurrent neoplasm in the distal esophagus.

In the upper abdomen there is some activity associated with a partially calcified lymph node which is best seen on image with the lymph node unfavorably changed in size compared to the prior study now measuring 18 mm in size and showing an SUV of 2.8. Scattered retroperitoneal lymph nodes are otherwise seen also unfavorably changed. In particular at the level of the lower kidneys between the aorta and cava there is a enlarged lymph node unfavorably changed in size with a maximal diameter of 2.4 cm and showing an SUV of 2.9. Uptake by scattered lymph nodes otherwise on either side of the retroperitoneum also seen. In addition a multiple lymph nodes are now seen extending into the iliac region on the left again unfavorably changed in size and activity with the activity as high as 4.8 seen in the proximal iliac region on the left. Some activity within lymph nodes in the right common iliac region also seen.

The attenuation CT again shows a Port-A-Cath overlying the right upper chest.

The calcified lymph node previously seen in the upper abdomen on the prior study is again seen without significant change in size. No activity associated with that lymph node seen. No pleural fluid identified. No lung nodules seen.

[page 8 of 8]
IMPRESSION: Unfavorable change compared to the prior study. Today's study shows activity in left axillary lymph nodes, distal esophagus, upper abdominal as well as retroperitoneal lymph nodes extending into iliac regions bilaterally while on the attenuation CT there is evidence for enlargement of left axillary lymph nodes, upper abdominal and retroperitoneal lymph nodes all suspicious for worsening neoplasm and representing unfavorable change.

Note on comparison to the prior study the activity previously seen diffusely distributed through the bones consistent with marrow uptake has decreased considerably over the interval.

Source: NCI Genomic Data Commons file 8ebfa299-0876-49b2-ace0-5f603a3a134a (ER0445 ER-AFFX Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).